Somatic mutation profile of tumor specimen MMRF_1577_1_BM_CD138pos (aliquot MMRF_1577_1_BM_CD138pos_T1_KBS5U_L03500) from MMRF case MMRF_1577, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 42.0 years (15,349 days).
Specimen MMRF_1577_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7cc692c-114f-45a4-8077-8f0fcbd7c5e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1577_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1577_1_PB_Whole_C2_KBS5U_L03504; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41a22774-f2ce-4194-8b74-0a51d3364d9a

The open-access MAF lists 50 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 16, Missense Mutation 15, Intron 8, Silent 4, Splice Site 2, RNA 2, 5'UTR 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 33/82 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CACNA1B | c.4840G>A p.A1614T | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs747965799, COSV53124044, COSV99500278; called by muse, mutect2, varscan2
- IGHV2-70 | c.289A>G p.N97D | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as rs368209907; called by muse, varscan2
- IGLV3-1 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.488); catalogued as rs555443658; called by muse, mutect2, varscan2
- MRPL9 | c.588+1G>A p.X196_splice | Splice Site (SNP) | VAF 23/79 reads (29%) | catalogued as rs1456900653; called by muse, mutect2, varscan2
- NEURL1B | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63940064; called by muse, mutect2, varscan2
- OR5D18 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.404); catalogued as rs1303498717, COSV61739109; called by muse, mutect2
- TDRD12 | c.2413G>A p.V805I | Missense Mutation (SNP) | VAF 65/104 reads (63%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs986839971; called by muse, mutect2, varscan2
- TSC2 | c.2904G>C p.E968D | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs765438249; called by muse, mutect2, varscan2
- UNC45B | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as rs775682897, COSV52093966, COSV99268830; called by muse, mutect2, varscan2
- ABCA12 | c.2472G>T p.K824N (on ENST00000272895 / NM_173076.3; = p.K506N on NM_015657.3) | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF17 | c.4238C>T p.A1413V | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); called by muse, mutect2
- DEK | c.-9G>C | Splice Region (SNP) | VAF 45/112 reads (40%) | called by muse, mutect2, varscan2
- MUC16 | c.26465G>T p.R8822I | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- PKHD1L1 | c.272A>T p.D91V | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- SPG11 | c.4161+2T>A p.X1387_splice | Splice Site (SNP) | VAF 30/63 reads (48%) | called by muse, mutect2, varscan2
- TAS2R20 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- TRIOBP | c.3487C>T p.P1163S | Missense Mutation (SNP) | VAF 78/154 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- ARHGAP26 | c.222T>C p.D74= | Silent (SNP) | VAF 125/181 reads (69%) | called by muse, mutect2, varscan2
- CETN1 | c.474C>T p.N158= | Silent (SNP) | VAF 101/212 reads (48%) | catalogued as COSV59121733; called by muse, mutect2, varscan2
- OSBPL5 | c.1173G>A p.T391= | Silent (SNP) | VAF 44/166 reads (27%) | catalogued as rs996287200, COSV99720076; called by muse, mutect2, varscan2
- ZFAND3 | c.396A>G p.K132= | Silent (SNP) | VAF 29/70 reads (41%) | called by muse, mutect2, varscan2
- ACTG2 | c.366+60A>G | Intron (SNP) | VAF 43/84 reads (51%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.*951G>A | 3'UTR (SNP) | VAF 87/118 reads (74%) | catalogued as rs191038659; called by muse, mutect2, varscan2
- ALPK2 | c.*8G>A | 3'UTR (SNP) | VAF 18/164 reads (11%) | catalogued as rs752722370; called by muse, mutect2, varscan2
- AMBN | c.*102G>A | 3'UTR (SNP) | VAF 16/47 reads (34%) | catalogued as COSV59826687; called by muse, mutect2, varscan2
- BCKDHB | c.*1079A>G | 3'UTR (SNP) | VAF 40/104 reads (38%) | called by muse, mutect2, varscan2
- CLDND1 | c.*52C>T | 3'UTR (SNP) | VAF 40/214 reads (19%) | called by muse, mutect2, varscan2
- CTTN | c.680-180T>G | Intron (SNP) | VAF 28/103 reads (27%) | called by muse, mutect2, varscan2
- CYP8B1 | chr3:42875892 A>G | 5'Flank (SNP) | VAF 31/88 reads (35%) | catalogued as rs905649105; called by muse, mutect2, varscan2
- HPS3 | c.*1176G>A | 3'UTR (SNP) | VAF 6/152 reads (4%) | called by muse, mutect2
- IER3 | c.*144C>A | 3'UTR (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- KCNK2 | c.*37G>A | 3'UTR (SNP) | VAF 44/169 reads (26%) | called by muse, mutect2, varscan2
- LHX2 | c.*237G>C | 3'UTR (SNP) | VAF 98/163 reads (60%) | called by muse, mutect2, varscan2
- LTB | c.208+89A>C | Intron (SNP) | VAF 45/92 reads (49%) | called by muse, mutect2, varscan2
- MAP4K3 | c.*1097G>T | 3'UTR (SNP) | VAF 44/81 reads (54%) | called by muse, mutect2, varscan2
- MYO15A | c.10350+187G>A | Intron (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- OPALIN | c.*1490T>G | 3'UTR (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- OR4K11P | n.567G>A | RNA (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.*6859T>A | 3'UTR (SNP) | VAF 49/150 reads (33%) | called by muse, mutect2, varscan2
- PTDSS2 | c.435+64G>A | Intron (SNP) | VAF 29/40 reads (73%) | called by muse, mutect2, varscan2
- RBM14 | c.337+1472T>C | Intron (SNP) | VAF 10/286 reads (3%) | called by muse, mutect2
- SH3GL2 | c.*349C>T | 3'UTR (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- SLC1A2 | c.18-5284G>A | Intron (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- SOX11 | c.*5610G>C | 3'UTR (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- SRSF4 | c.-76C>T | 5'UTR (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- TMEM245 | c.*890A>C | 3'UTR (SNP) | VAF 42/138 reads (30%) | called by muse, mutect2, varscan2
- TTPA | c.*1128A>T | 3'UTR (SNP) | VAF 30/53 reads (57%) | called by muse, mutect2, varscan2
- UBE2DNL | n.627G>A | RNA (SNP) | VAF 81/82 reads (99%) | catalogued as rs1451079701; called by muse, mutect2, varscan2
- UNC13C | c.5457+521_5457+523del | Intron (DEL) | VAF 83/164 reads (51%) | catalogued as rs1454819482; called by pindel, varscan2
